Somatic mutation profile of tumor specimen TCGA-ZN-A9VU-01A (aliquot TCGA-ZN-A9VU-01A-11D-A39R-32) from TCGA case TCGA-ZN-A9VU, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 70.4 years (25,714 days).
Specimen TCGA-ZN-A9VU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3bd256bf-7364-4add-aff9-e7a532dde49b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZN-A9VU-10A (Blood Derived Normal), aliquot TCGA-ZN-A9VU-10A-01D-A39U-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80fd76a2-c757-4c9c-bf5c-e81964b53c47

The open-access MAF lists 32 somatic variants for this specimen: 29 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Frame Shift Del 2, Silent 2, Nonsense Mutation 1, Nonstop Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAPN15 | c.1904C>T p.S635F | Missense Mutation (SNP) | VAF 75/275 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1376177778; called by muse, mutect2, varscan2
- DCLRE1B | c.286G>T p.D96Y | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56724067, COSV99870641; called by muse, mutect2, varscan2
- FZD9 | c.873C>A p.S291R | Missense Mutation (SNP) | VAF 32/406 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.036); catalogued as COSV60670062; called by muse, mutect2
- GALNT14 | c.1250C>T p.S417F | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.56); catalogued as rs1045023, COSV100204265; called by muse, mutect2, varscan2
- HK3 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 55/190 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.033); catalogued as rs766901550, COSV52837044; called by muse, mutect2, varscan2
- IRF4 | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.82); catalogued as rs377483798; called by muse, mutect2, varscan2
- SOAT1 | c.1084C>A p.L362M | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.259); catalogued as rs765422379; called by muse, mutect2, varscan2
- TLL2 | c.859A>T p.S287C | Missense Mutation (SNP) | VAF 59/173 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV63575365; called by muse, mutect2, varscan2
- VANGL2 | c.1048C>T p.R350* | Nonsense Mutation (SNP) | VAF 17/52 reads (33%) | catalogued as rs1046298527; called by muse, mutect2, varscan2
- AKAP6 | c.392T>G p.L131R | Missense Mutation (SNP) | VAF 62/221 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BAP1 | c.2189_*7del | Nonstop Mutation (DEL) | VAF 50/106 reads (47%) | called by mutect2, pindel, varscan2
- BAZ2B | c.5036A>C p.E1679A | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- BLNK | c.7A>G p.K3E | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- CAPN2 | c.1117G>C p.G373R | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAPRIN2 | c.1825C>G p.L609V | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- CFAP69 | c.1846G>T p.D616Y | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FGD6 | c.1049G>A p.C350Y | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated, low confidence (0.88); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- GLI1 | c.2953G>A p.A985T | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- HNRNPR | c.1748C>G p.S583C | Missense Mutation (SNP) | VAF 86/343 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- KYNU | c.426T>A p.H142Q | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- MACF1 | c.22118C>A p.T7373N (on ENST00000372915; = p.T5418N on NM_012090.5) | Missense Mutation (SNP) | VAF 27/127 reads (21%) | called by muse, mutect2, varscan2
- PBRM1 | c.4685del p.G1562Efs*34 (on ENST00000296302 / NM_001366071.2; = p.G1455Efs*34 on NM_018313.5) | Frame Shift Del (DEL) | VAF 40/111 reads (36%) | called by mutect2, pindel, varscan2
- PPA1 | c.697A>G p.K233E | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.019); called by muse, mutect2
- PSG7 | c.543G>T p.W181C | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, varscan2
- SIK3 | c.3185G>A p.R1062K (on ENST00000445177 / NM_001366686.2; = p.R1020K on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/178 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- SPATA13 | c.1852del p.M618Cfs*103 | Frame Shift Del (DEL) | VAF 60/143 reads (42%) | called by mutect2, pindel, varscan2
- SPTA1 | c.5299C>T p.P1767S | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- STAB1 | c.2642C>T p.P881L | Missense Mutation (SNP) | VAF 79/196 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- ZNF664 | c.481C>T p.H161Y | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IL17RA | c.2325C>T p.L775= | Silent (SNP) | VAF 45/104 reads (43%) | catalogued as rs1261083901; called by muse, mutect2, varscan2
- STK31 | c.2652G>A p.S884= | Silent (SNP) | VAF 29/98 reads (30%) | catalogued as rs138551298, COSV100669224, COSV63459239; called by muse, mutect2, varscan2
- HNF4A | c.115+1114T>G | Intron (SNP) | VAF 31/87 reads (36%) | called by muse, mutect2, varscan2
